Somatic mutation profile of tumor specimen TCGA-SR-A6MQ-01A (aliquot TCGA-SR-A6MQ-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Aortic body and other paraganglia; Age at diagnosis: 61.9 years (22,621 days).
Specimen TCGA-SR-A6MQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3da40cdc-3071-4fed-9ce9-030a6768a270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MQ-10A (Blood Derived Normal), aliquot TCGA-SR-A6MQ-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d72dec3-3e10-4679-adca-3ea5f1ad09d9

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.9703G>A p.A3235T | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV64245062; called by muse, mutect2
- MSN | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761463986; called by muse, mutect2, varscan2
- APAF1 | c.3303A>G p.S1101= (on ENST00000551964 / NM_181861.2; = p.S1047= on NM_001160.3) | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- COL12A1 | c.5895C>T p.R1965= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs376241836; ClinVar: likely benign; called by muse, mutect2
- TDRD7 | c.3183C>T p.N1061= | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- TTN | c.10361-4719A>T | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
